EXCEPTIONAL_RESPONDERS case ER-AE6D — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/265d4c1d-9aae-4e28-b2d1-653ac87a0726

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,277 days); Year of diagnosis: 2014; AJCC staging edition: 7th; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 947 days (2.6 years); Days to best overall response: 176 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 10 days; Days to treatment end: 171 days.

Follow-up (1 entry)
- Days to follow up: 947 days (2.6 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 3 days; Days progression-free: 947 days (2.6 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AE6D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AE6D-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
